Somatic mutation profile of tumor specimen TCGA-HU-A4GN-01A (aliquot TCGA-HU-A4GN-01A-11D-A25D-08) from TCGA case TCGA-HU-A4GN, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,288 days).
Specimen TCGA-HU-A4GN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8216de9b-83f6-4e65-8c45-50c1b1922ca4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GN-10A (Blood Derived Normal), aliquot TCGA-HU-A4GN-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04fcf2ae-0f6c-4b26-820b-f6903c4f6556

The open-access MAF lists 1,303 somatic variants for this specimen: 982 protein-altering or splice-affecting, 291 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 670, Silent 291, Frame Shift Del 212, Frame Shift Ins 33, Nonsense Mutation 33, In Frame Del 15, Splice Site 13, Intron 12, RNA 7, Splice Region 5, 3'UTR 4, 5'UTR 4.

Variants (750 of 1,303; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AVIL | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.922); catalogued as rs1334894971, COSV57681496; ClinVar: pathogenic; called by muse, mutect2
- CTSK | c.990A>G p.*330Wext*19 | Nonstop Mutation (SNP) | VAF 23/257 reads (9%) | catalogued as rs74315301, CM960427, COSV55011535; ClinVar: pathogenic; called by muse, mutect2
- EFNB1 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28936069, CM041297, COSV99214963; ClinVar: pathogenic; called by muse, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 27/116 reads (23%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- NEK1 | c.1908del p.V637Cfs*34 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs775849720; ClinVar: likely pathogenic; called by mutect2, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 21/91 reads (23%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- RRAS2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782457908, COSV56329532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.11707C>T p.R3903* | Nonsense Mutation (SNP) | VAF 34/179 reads (19%) | catalogued as rs774906736, CM099019, COSV66538528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC12A1 | c.1833del p.F611Lfs*32 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs1057520304; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 20/125 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs786201057, CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; ClinVar: likely pathogenic / pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- A2M | c.142T>C p.C48R | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59385386; called by muse, mutect2, varscan2
- ABCA12 | c.2226G>A p.M742I (on ENST00000272895 / NM_173076.3; = p.M424I on NM_015657.3) | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55955903; called by muse, mutect2, varscan2
- ABCA3 | c.3913C>T p.R1305W | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57052365; called by muse, mutect2, varscan2
- ABCC3 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs543738423, COSV53317946; called by muse, mutect2, varscan2
- ABCF3 | c.1437-2A>G p.X479_splice | Splice Site (SNP) | VAF 38/115 reads (33%) | catalogued as COSV53052030, COSV99491395; called by muse, mutect2, varscan2
- AC068580.4 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.883); catalogued as rs767282477, COSV52587895; called by mutect2, varscan2
- ACAT1 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56187223; called by muse, mutect2, varscan2
- ACE2 | c.218del p.L73* | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | catalogued as COSV99382940; called by mutect2, pindel, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 24/109 reads (22%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 32/124 reads (26%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS17 | c.873+1G>A p.X291_splice | Splice Site (SNP) | VAF 21/145 reads (14%) | catalogued as rs1160509052, CS146271, COSV51477922; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS20 | c.4670A>C p.E1557A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV67130215; called by muse, mutect2, varscan2
- ADAMTS9 | c.4201G>T p.G1401C | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55779387; called by muse, mutect2
- ADCY8 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53904375; called by muse, mutect2
- ADGRV1 | c.17819T>G p.L5940R | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67983403; called by muse, mutect2, varscan2
- ADIPOQ | c.215-2A>G p.X72_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as rs769314249, COSV57858918; called by muse, mutect2
- AGO2 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV55046684; called by muse, mutect2
- AHNAK | c.11318A>G p.D3773G | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as COSV57210935; called by muse, mutect2
- AKAP11 | c.1610del p.N537Ifs*8 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs764225198; called by mutect2, pindel, varscan2
- AKAP5 | c.247A>G p.K83E | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57742279; called by muse, mutect2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKR1C4 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV54123003, COSV54126061; called by muse, mutect2, varscan2
- ALDH6A1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760486330, COSV63246232; called by muse, mutect2, varscan2
- ALOX15B | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV66479329; called by muse, mutect2, varscan2
- ALPK2 | c.6349G>T p.A2117S | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV64492193; called by muse, mutect2
- ALPK3 | c.4318C>A p.R1440S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.391); catalogued as COSV51932489; called by muse, mutect2, varscan2
- AMPD1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs12566550, COSV62415655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANGPT2 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57336417; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.862); catalogued as rs770011324, COSV51839754; called by muse, mutect2, varscan2
- ANKRD50 | c.4112G>A p.S1371N | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV72385402; called by muse, mutect2, varscan2
- ANO1 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1555047278, COSV60281442; called by muse, mutect2, varscan2
- ANO6 | c.2530G>A p.V844I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.084); catalogued as rs773140175, COSV57659952; called by mutect2, varscan2
- ANO8 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV50175651; called by muse, mutect2
- AP3D1 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs771788983, COSV61425179; called by muse, mutect2, varscan2
- AP4E1 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55916439; called by muse, mutect2, varscan2
- AP5Z1 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760734290, COSV62241290; called by muse, mutect2, varscan2
- APEH | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs145125345; called by muse, mutect2, varscan2
- APOB | c.6827T>C p.I2276T | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1553383646, COSV51932085; called by muse, mutect2, varscan2
- APOL5 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV50766718; called by muse, mutect2, varscan2
- APOL6 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1212740082, COSV68749450; called by muse, mutect2, varscan2
- APP | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV60997434; called by muse, mutect2, varscan2
- APRT | c.521_523del p.F174del | In Frame Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs121912681; called by pindel, varscan2
- ARF1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as rs1447268730, COSV55254611; called by muse, mutect2, varscan2
- ARHGAP5 | c.1393T>C p.Y465H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.781); catalogued as COSV61535058; called by muse, mutect2, varscan2
- ARHGEF19 | c.1575G>T p.L525F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54616201; called by muse, mutect2, varscan2
- ARHGEF2 | c.1321C>T p.R441C (on ENST00000361247 / NM_001162383.2; = p.R413C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1281348315, COSV58109762; called by muse, mutect2, varscan2
- ARHGEF9 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53637261; called by muse, mutect2
- ARID3A | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55044172; called by muse, varscan2
- ARMC4 | c.94A>T p.K32* | Nonsense Mutation (SNP) | VAF 5/67 reads (7%) | catalogued as COSV59461625; called by muse, mutect2
- ARSF | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as rs867577161, COSV63839382; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs747570359; called by mutect2, varscan2
- ASPHD1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs1433020211, COSV58098898; called by muse, mutect2
- ASS1 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV61689028; called by muse, mutect2, varscan2
- ASTN2 | c.2972G>A p.R991H (on ENST00000313400 / NM_001365069.1; = p.R940H on NM_014010.5) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs746758044, COSV56003044; called by muse, mutect2, varscan2
- ATIC | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs549649169, COSV52692704; called by muse, mutect2, varscan2
- ATP13A1 | c.1787C>T p.T596M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as rs973955925, COSV52284834; called by muse, mutect2, varscan2
- ATP2A2 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV58043691; called by muse, mutect2, varscan2
- ATP6V0D1 | c.482-2A>C p.X161_splice | Splice Site (SNP) | VAF 9/80 reads (11%) | catalogued as COSV52097368; called by muse, mutect2
- ATP6V0D1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759666597, COSV52097376; called by muse, mutect2, varscan2
- ATP6V1C2 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1474755358, COSV55359546; called by muse, mutect2, varscan2
- ATP7B | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs121907994, CM980173, COSV54435550; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- ATP8B3 | c.1595A>G p.Y532C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV59542028; called by muse, mutect2
- ATXN10 | c.393T>C p.A131= | Splice Region (SNP) | VAF 7/44 reads (16%) | catalogued as COSV53295560; called by muse, mutect2
- ATXN2L | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs562015209, COSV57368753; called by muse, mutect2, varscan2
- ATXN7L3 | c.605G>A p.R202H (on ENST00000389384 / NM_001382309.1; = p.R209H on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs751741019, COSV60228645; called by mutect2, varscan2
- B4GALT3 | c.1105A>G p.M369V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV60527031; called by muse, mutect2
- BAIAP2L1 | c.858del p.A287Lfs*11 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | catalogued as COSV50058748; called by mutect2, pindel, varscan2
- BAZ1A | c.2546A>G p.Q849R | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.351); catalogued as rs1280358408, COSV62409878; called by muse, mutect2, varscan2
- BAZ2A | c.4817T>C p.L1606P | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51635153; called by muse, mutect2, varscan2
- BCAS1 | c.862A>G p.M288V | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV65085307; called by muse, mutect2, varscan2
- BCL6B | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs756736408, COSV53427462, COSV99546550; called by muse, mutect2
- BDP1 | c.1229del p.C410Lfs*4 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as COSV62430764; called by mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BEST3 | c.45del p.F15Lfs*32 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | catalogued as rs1184020574; called by mutect2, varscan2
- BEX3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55421170; called by muse, mutect2, varscan2
- BIRC6 | c.5888C>T p.A1963V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV70198172; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOP1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as rs1489687049; called by muse, mutect2
- BRAT1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100500641, COSV61397073; called by muse, mutect2, varscan2
- BRCA1 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); catalogued as COSV58788433; called by muse, mutect2, varscan2
- BRCA2 | c.10123A>G p.S3375G | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1060502481, COSV66337176; ClinVar: uncertain significance; called by muse, mutect2
- BRD1 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53456354; called by muse, mutect2, varscan2
- BRD8 | c.3488G>A p.R1163H | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs757840348, COSV54522018; called by muse, mutect2, varscan2
- BRWD1 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs931536728, COSV60894685; called by muse, mutect2
- C12orf4 | c.914A>G p.H305R | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1024076420, COSV54206565; called by muse, mutect2
- CACNA1D | c.3338C>T p.S1113L (on ENST00000350061 / NM_001128840.3; = p.S1133L on NM_000720.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1363939471, COSV55444282; called by muse, mutect2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs760298114; called by mutect2, pindel, varscan2
- CAMK2B | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs758417712, COSV51659505; called by muse, mutect2, varscan2
- CAMK2D | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); catalogued as COSV56429062; called by muse, mutect2, varscan2
- CAPN12 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53145136; called by muse, mutect2, varscan2
- CCDC153 | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 34/144 reads (24%) | catalogued as rs745729530; called by mutect2, varscan2
- CCDC30 | c.913C>T p.L305F (on ENST00000340612; = p.L262F on NM_001080850.3) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59605974; called by muse, mutect2, varscan2
- CCDC80 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs777714728, COSV52816242; called by muse, mutect2, varscan2
- CCNE2 | c.318C>A p.S106R | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57375812; called by muse, mutect2
- CCNL1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs749964157, COSV55819015; called by muse, mutect2, varscan2
- CCNQ | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1427113628, COSV52344180; called by muse, mutect2, varscan2
- CCR3 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs201751920, COSV62462742; called by muse, mutect2, varscan2
- CD163L1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs775796852, COSV58014580, COSV58016913; called by muse, mutect2, varscan2
- CD320 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs372399234, COSV56848233; called by muse, mutect2, varscan2
- CDH11 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV51756239; called by muse, mutect2, varscan2
- CDH15 | c.60G>T p.L20F | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV57023574; called by muse, mutect2, varscan2
- CDH4 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200506111, COSV64641310; called by muse, mutect2, varscan2
- CDH8 | c.2212G>C p.A738P | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54894175; called by muse, mutect2
- CDK5RAP2 | c.5077G>A p.D1693N | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV62573608; called by muse, mutect2, varscan2
- CDSN | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as rs1012807064, COSV52537785; called by muse, mutect2, varscan2
- CDX4 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV65171578; called by muse, mutect2, varscan2
- CEACAM4 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV55730785, COSV55731298; called by muse, mutect2
- CELA1 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV53329597; called by muse, mutect2, varscan2
- CELSR2 | c.1757G>A p.G586D | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54769790; called by muse, mutect2
- CELSR3 | c.3224G>T p.R1075L | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV50849009; called by muse, mutect2, varscan2
- CENPF | c.761C>A p.P254Q | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65274238; called by muse, mutect2, varscan2
- CENPU | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs200975207; called by muse, mutect2, varscan2
- CEP68 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV53124450; called by muse, mutect2, varscan2
- CES4A | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs766181305, COSV58652952; called by muse, mutect2, varscan2
- CFAP20DC | c.2192G>A p.R731H (on ENST00000482387 / NM_001351530.2; = p.R480H on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs766560118, COSV55918743; called by muse, mutect2, varscan2
- CFAP97 | c.306del p.K102Nfs*23 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs1305639008; called by mutect2, varscan2
- CHAF1A | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs753346844, COSV56671403; called by muse, mutect2, varscan2
- CHD7 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.242); catalogued as rs762290343, COSV71109300; called by muse, mutect2, varscan2
- CHMP6 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs767639574, COSV57327253; called by muse, mutect2, varscan2
- CHRNG | c.1531C>A p.P511T | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51471649; called by muse, mutect2, varscan2
- CHST2 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV58885256; called by muse, mutect2
- CIR1 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as rs773178784, COSV59595216; called by muse, mutect2
- CLASRP | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs906466848, COSV55515712; called by muse, mutect2, varscan2
- CLCN2 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55600593; called by muse, mutect2
- CLCN7 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1360191307, COSV51969895; called by muse, mutect2
- CLEC3B | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV56109611; called by muse, mutect2, varscan2
- CLK3 | c.722G>A p.R241Q (on ENST00000395066 / NM_001130028.1; = p.R93Q on NM_003992.4) | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as rs766299793, COSV61412362; called by muse, mutect2, varscan2
- CLK3 | c.1366_1368del p.E456del (on ENST00000395066 / NM_001130028.1; = p.E308del on NM_003992.4) | In Frame Del (DEL) | VAF 23/114 reads (20%) | catalogued as rs1171107440; called by pindel, varscan2
- CLPTM1L | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1249725762, COSV57990171; called by muse, mutect2, varscan2
- CMIP | c.377C>T p.P126L (on ENST00000537098 / NM_198390.2; = p.P32L on NM_030629.3) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.992); catalogued as rs1027281056, COSV73344787, COSV73344853; called by muse, mutect2, varscan2
- CMYA5 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV71405382; called by muse, mutect2
- CNGA1 | c.1969A>G p.K657E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs540881872, COSV62053948; called by muse, mutect2, varscan2
- CNGA4 | c.1445C>G p.A482G | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV66005683; called by muse, mutect2, varscan2
- CNKSR3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.368); catalogued as rs769098143, COSV72161748; called by muse, mutect2
- CNOT3 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs375507060; called by muse, mutect2, varscan2
- CNTNAP5 | c.1085A>T p.E362V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70482477; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs374805044; called by mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL11A2 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs749748036, COSV59495874; called by muse, varscan2
- COL12A1 | c.7303G>A p.G2435S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59394078, COSV59394500, COSV59398722; called by muse, mutect2, varscan2
- COL12A1 | c.5894G>A p.R1965H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs199747984, COSV59392343; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 9/55 reads (16%) | catalogued as rs760493024; called by mutect2, varscan2
- COL6A6 | c.2524G>A p.G842S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV62022877; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.3143C>T p.T1048M | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as rs148571756; called by muse, mutect2, varscan2
- CPE | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs376055726; called by muse, mutect2, varscan2
- CPSF1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs1554864694; called by muse, mutect2
- CPT1C | c.946A>G p.I316V | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV54918703; called by muse, mutect2
- CPT1C | c.1396C>A p.L466I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.091); catalogued as COSV54918710; called by muse, mutect2
- CPXM2 | c.1755del p.S586Pfs*9 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as COSV53858100; called by mutect2, pindel
- CPXM2 | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868029784, COSV53860155; called by muse, mutect2, varscan2
- CRADD | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs779660963, COSV60553130; called by muse, mutect2, varscan2
- CREBBP | c.4981A>G p.M1661V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52120478; called by muse, mutect2, varscan2
- CRISPLD1 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 12/114 reads (11%) | catalogued as rs1368887327, COSV51546678; called by mutect2, varscan2
- CRY1 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as rs767156491, COSV50481923; called by muse, mutect2, varscan2
- CRYGB | c.251del p.P84Rfs*8 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | catalogued as rs1559328208, COSV53679868; called by pindel, varscan2
- CSF2RA | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.445); catalogued as rs371464087, COSV62624348; called by muse, mutect2, varscan2
- CSK | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54973525; called by muse, mutect2, varscan2
- CSMD1 | c.5144G>A p.R1715Q (on ENST00000520002; = p.R1714Q on NM_033225.6) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs747749324, COSV59310534; called by muse, mutect2, varscan2
- CSNK1G2 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV55336947; called by muse, mutect2, varscan2
- CTNND2 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs376760091; called by muse, mutect2, varscan2
- CUL1 | c.1840T>C p.Y614H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57388037; called by muse, mutect2
- CUL5 | c.331T>C p.F111L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67608679; called by muse, mutect2, varscan2
- CUL7 | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54815479; called by muse, mutect2, varscan2
- CUX1 | c.1289del p.P430Lfs*27 | Frame Shift Del (DEL) | VAF 30/130 reads (23%) | catalogued as rs782381199; called by mutect2, pindel, varscan2
- CUX2 | c.2590C>T p.R864W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767329512, COSV55629706; called by muse, varscan2
- CXCL17 | c.277C>A p.H93N | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV99734370; called by muse, mutect2
- CYFIP2 | c.3352G>A p.E1118K (on ENST00000616178 / NM_001291722.2; = p.E1093K on NM_014376.4) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV59034733; called by muse, mutect2, varscan2
- CYP26A1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV56417843; called by muse, mutect2
- CYP4F22 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV54107943; called by muse, mutect2
- CYP51A1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV50151389; called by muse, mutect2
- CYTH4 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs200267703, COSV50632119; called by muse, mutect2, varscan2
- CYTIP | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV51633357; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs751187768; called by mutect2, varscan2
- DAGLA | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57195431; called by muse, mutect2
- DCANP1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.263); catalogued as COSV72345778; called by muse, mutect2
- DDX19B | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55363669; called by muse, mutect2, varscan2
- DENND1A | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV65324629; called by muse, mutect2, varscan2
- DENND2B | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV58202884; called by muse, mutect2, varscan2
- DENND2B | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs372527362, COSV58202891; called by muse, mutect2
- DHTKD1 | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as rs371749570, COSV53802972; called by muse, mutect2, varscan2
- DHX29 | c.4082C>T p.T1361M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as rs752689422, COSV52417837; called by muse, mutect2, varscan2
- DHX34 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs761357245, COSV60895115; called by muse, mutect2, varscan2
- DHX36 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757655851, COSV57672005; called by muse, mutect2, varscan2
- DHX36 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 58/277 reads (21%) | catalogued as rs1223273053, COSV57672020; called by muse, mutect2, varscan2
- DLGAP3 | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs764135834, COSV52393369; called by muse, mutect2, varscan2
- DLX5 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs769554704, COSV56032197; called by muse, mutect2, varscan2
- DMRT3 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 14/113 reads (12%) | catalogued as COSV51903885; called by muse, mutect2, varscan2
- DMTF1 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs1435799173, COSV57538340; called by muse, mutect2, varscan2
- DNAAF4 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.42); catalogued as COSV58248187; called by muse, mutect2, varscan2
- DNAH9 | c.12592A>G p.T4198A | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as COSV52345424; called by muse, mutect2, varscan2
- DNM2 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 15/153 reads (10%) | catalogued as COSV58959871, COSV58960176; called by muse, mutect2, varscan2
- DNM2 | c.2377dup p.L793Pfs*31 (on ENST00000355667 / NM_001005360.3; = p.L789Pfs*31 on NM_004945.3) | Frame Shift Ins (INS) | VAF 16/92 reads (17%) | catalogued as rs764391392, COSV53034926; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK9 | c.3395G>A p.R1132H (on ENST00000376460 / NM_001366676.2; = p.R1133H on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs373604227; called by muse, mutect2, varscan2
- DONSON | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as rs753740715, COSV51677039; called by muse, mutect2, varscan2
- DPF1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62792559; called by muse, mutect2, varscan2
- DPP6 | c.1183G>A p.A395T (on ENST00000377770 / NM_001364500.2; = p.A333T on NM_001936.5) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs373224292, COSV100125862; called by muse, mutect2, varscan2
- DSP | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761051181, CM157466, COSV65792342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSTYK | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs150778354; called by muse, mutect2, varscan2
- DUOX1 | c.3317G>A p.R1106H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs1567017744, COSV58479592; called by muse, mutect2, varscan2
- DYNLRB1 | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55963937; called by muse, mutect2, varscan2
- E2F7 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59739034; called by muse, mutect2, varscan2
- E2F8 | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 40/250 reads (16%) | catalogued as COSV51462992; called by muse, mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs746509911; called by mutect2, varscan2
- EDA2R | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV53630997; called by muse, mutect2, varscan2
- EDRF1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV100523872; called by muse, mutect2, varscan2
- EEF1G | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs756104285, COSV100240623; called by muse, varscan2
- EFHC1 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV64136100; called by muse, mutect2, varscan2
- EGR1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV53518894; called by muse, mutect2, varscan2
- EID3 | c.389A>T p.N130I | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61598726; called by muse, mutect2, varscan2
- EIF2AK4 | c.4426C>T p.R1476C | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1161134551, COSV55467484; called by muse, mutect2, varscan2
- EPB41L3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs780187679, COSV59450551; called by muse, mutect2, varscan2
- EPHA2 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64452841; called by muse, mutect2, varscan2
- EPHA4 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs771415392, COSV56030914; called by muse, mutect2, varscan2
- EPN3 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753177479, COSV52139195; called by muse, mutect2, varscan2
- EPS8L3 | c.1730G>A p.R577Q (on ENST00000361965 / NM_133181.4; = p.R547Q on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); catalogued as rs577159080, COSV62609165; called by muse, mutect2, varscan2
- EPS8L3 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs773474367, COSV62609250; called by muse, mutect2, varscan2
- ERC2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV55615535; called by muse, mutect2, varscan2
- ERCC2 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs144511865; called by muse, mutect2, varscan2
- ERCC3 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53425431; called by muse, mutect2
- ERCC6 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs759569215, COSV63389297; called by muse, mutect2, varscan2
- ESPL1 | c.3035T>C p.L1012S | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57758840; called by muse, mutect2
- EXO1 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV62217197; called by muse, mutect2, varscan2
- EXOC1 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62120006; called by muse, mutect2, varscan2
- EXOC3L1 | c.329T>C p.M110T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52045879; called by muse, mutect2, varscan2
- EXTL3 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs376869552; called by muse, varscan2
- EYA4 | c.1873T>C p.W625R (on ENST00000531901 / NM_001301013.1; = p.W619R on NM_004100.5) | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62050137, COSV62063546; called by muse, mutect2, varscan2
- F2 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV61315519; called by muse, mutect2, varscan2
- FAF1 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); catalogued as COSV65637902; called by muse, mutect2, varscan2
- FAM107A | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs565978154, COSV62980545; called by muse, mutect2, varscan2
- FAM163B | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1034593997; called by muse, mutect2, varscan2
- FANCG | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1195912341, COSV62720249; called by muse, mutect2, varscan2
- FARP1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs200784439, COSV60335166; called by muse, mutect2, varscan2
- FARSA | c.437dup p.Q147Tfs*3 | Frame Shift Ins (INS) | VAF 13/100 reads (13%) | catalogued as rs746493788; called by mutect2, varscan2
- FAT1 | c.6793G>A p.A2265T | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1330014464, COSV71673403; called by muse, mutect2, varscan2
- FAT4 | c.9842G>T p.C3281F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV58680392; called by muse, mutect2, varscan2
- FAT4 | c.10850G>A p.R3617Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs746784092, COSV58675168, COSV58680409; called by muse, mutect2, varscan2
- FAT4 | c.11416G>A p.D3806N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV58680424; called by muse, mutect2, varscan2
- FBXO38 | c.467G>A p.W156* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | catalogued as COSV57027087; called by muse, mutect2, varscan2
- FBXW11 | c.869A>T p.E290V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV51608436; called by muse, mutect2, varscan2
- FDPS | c.518A>C p.D173A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63114318; called by muse, mutect2, varscan2
- FGD1 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124157, COSV64308546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD2 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1290492014, COSV51463245; called by muse, mutect2, varscan2
- FIG4 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as rs866187682, COSV57786924; called by muse, mutect2
- FILIP1 | c.1000A>G p.K334E | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV52727496; called by muse, mutect2, varscan2
- FJX1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.659); catalogued as COSV58552843; called by muse, mutect2, varscan2
- FLG | c.7201C>T p.R2401C | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs553468192, COSV64243028; called by muse, mutect2, varscan2
- FLRT3 | c.167T>C p.I56T | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV53973201; called by muse, mutect2, varscan2
- FLYWCH1 | c.1759G>A p.A587T (on ENST00000253928 / NM_001308068.2; = p.A586T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.289); catalogued as COSV54145246; called by muse, mutect2
- FNDC7 | c.1342T>C p.S448P | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54752520; called by muse, mutect2
- FOXD2 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as COSV58303928; called by muse, mutect2, varscan2
- FUT6 | c.171del p.A58Pfs*6 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs1568406009, COSV99744655; called by mutect2, pindel, varscan2
- GALNT8 | c.1099T>C p.F367L | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52896733; called by muse, mutect2, varscan2
- GANC | c.856A>G p.N286D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | PolyPhen probably damaging (0.999); catalogued as COSV58808483; called by muse, mutect2, varscan2
- GAREM1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs757104286, COSV52508290; called by muse, mutect2, varscan2
- GAS7 | c.395A>G p.Y132C (on ENST00000432992 / NM_201433.2; = p.Y72C on NM_201432.2) | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.24); catalogued as rs1371468090, COSV60434930; called by muse, mutect2, varscan2
- GFPT2 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV53807876; called by muse, mutect2, varscan2
- GFUS | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV55306637; called by muse, mutect2, varscan2
- GHRHR | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58195741, COSV58196214; called by muse, mutect2, varscan2
- GLI3 | c.3560A>G p.Q1187R | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV67887499; called by muse, mutect2
- GLI4 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV60681848; called by muse, mutect2, varscan2
- GLT1D1 | c.878A>G p.Q293R (on ENST00000442111 / NM_001366889.1; = p.Q213R on NM_144669.3) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV55877904, COSV55880621; called by muse, mutect2, varscan2
- GLT8D1 | c.375T>G p.I125M | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV56477253; called by muse, mutect2
- GMIP | c.2387A>G p.Q796R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV52555581; called by muse, mutect2
- GNAT2 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as COSV63554786; called by muse, varscan2
- GNE | c.2249G>A p.R750H (on ENST00000396594 / NM_001128227.3; = p.R719H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1424828612, COSV64951670; called by muse, mutect2, varscan2
- GPATCH4 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV58039497; called by muse, mutect2, varscan2
- GPD2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs141792291; called by muse, mutect2, varscan2
- GPR162 | c.1417G>T p.G473C (on ENST00000311268 / NM_019858.2; = p.G189C on NM_014449.2) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.439); catalogued as COSV51832511; called by muse, mutect2, varscan2
- GPR32 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs1007134018, COSV54514243; called by muse, mutect2, varscan2
- GPR37 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as COSV58256503; called by muse, mutect2, varscan2
- GPRC5B | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs765829170, COSV56026047; called by muse, mutect2, varscan2
- GPRC5B | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56026064; called by muse, mutect2
- GRHL3 | c.1295G>A p.G432D (on ENST00000350501 / NM_198174.3; = p.G437D on NM_021180.3) | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.36); catalogued as rs1281509789, COSV52565871; called by muse, mutect2
- GRIK5 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs755808188, COSV53477519; called by muse, mutect2, varscan2
- GRM5 | c.1042A>C p.T348P | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV59601246; called by muse, mutect2, varscan2
- GSE1 | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53671346; called by muse, mutect2, varscan2
- GTF2F1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs1448489564, COSV55532071; called by muse, mutect2
- GUCY1B1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776905298, COSV52375040; called by muse, mutect2, varscan2
- HAS3 | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV54706672; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HCN4 | c.1879A>G p.T627A | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV56082882; called by muse, mutect2, varscan2
- HCRTR1 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1025311928, COSV65483633; called by muse, mutect2, varscan2
- HCST | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52887555, COSV99385629; called by muse, mutect2, varscan2
- HDLBP | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60494424; called by muse, mutect2, varscan2
- HDLBP | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60494442; called by muse, mutect2
- HELB | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56073410; called by muse, mutect2, varscan2
- HELLS | c.1840del p.R614Efs*11 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs745837238; called by mutect2, varscan2
- HEMK1 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs945411000, COSV51750357; called by muse, mutect2, varscan2
- HIP1 | c.3101C>T p.T1034I | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV61185076; called by muse, mutect2, varscan2
- HIVEP3 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); catalogued as rs953638873, COSV56013759; called by muse, mutect2
- HLX | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV65044675; called by muse, mutect2, varscan2
- HNRNPA1 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52936431; called by muse, varscan2
- HNRNPH2 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.678); catalogued as COSV104374341, COSV54508884; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1073T>A p.I358N | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54561737, COSV54564200; called by muse, mutect2, varscan2
- HOXB6 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV53312531; called by muse, mutect2, varscan2
- HSPG2 | c.10855A>G p.S3619G | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.872); catalogued as COSV65933030; called by muse, mutect2, varscan2
- HTR2A | c.1212A>C p.K404N | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV66327076; called by muse, mutect2, varscan2
- HTR3E | c.1070C>T p.P357L (on ENST00000415389 / NM_001256613.1; = p.P372L on NM_182589.2) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs200919072, COSV58945851, COSV58946928; called by muse, mutect2, varscan2
- IFNL3 | c.491del p.K164Rfs*23 | Frame Shift Del (DEL) | VAF 12/95 reads (13%) | catalogued as rs1331362711; called by mutect2, pindel, varscan2
- IGF1 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV61032313; called by muse, mutect2, varscan2
- IGHMBP2 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54821767; called by muse, mutect2
- IGLV1-47 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as rs996453363; called by muse, mutect2, varscan2
- IGSF10 | c.3353G>T p.S1118I | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56784049; called by muse, mutect2, varscan2
- IGSF3 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761318910, COSV59594462; called by muse, mutect2
- IKZF1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778910457, COSV58784598; called by muse, mutect2, varscan2
- IL16 | c.2580G>T p.Q860H (on ENST00000302987 / NM_172217.5; = p.Q159H on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100268029; called by muse, mutect2, varscan2
- IL21R | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767388017, COSV61969748; called by muse, mutect2, varscan2
- ILVBL | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038376866, COSV54618975; called by muse, mutect2, varscan2
- INPP5K | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57440664; called by muse, mutect2, varscan2
- INTS10 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.356); catalogued as rs770188814, COSV67604028; called by muse, mutect2, varscan2
- INTS13 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53902238; called by muse, mutect2, varscan2
- IQCH | c.2569T>C p.Y857H | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1342507401, COSV60051542; called by muse, mutect2, varscan2
- IQCN | c.2857del p.A953Pfs*96 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | catalogued as rs781149862; called by mutect2, pindel, varscan2
- IRF2BPL | c.2119A>G p.M707V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.014); catalogued as COSV53146802; called by muse, mutect2, varscan2
- IRS1 | c.3242G>A p.R1081H | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs372681714, COSV59335467; called by muse, mutect2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS1 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 27/128 reads (21%) | catalogued as COSV59335477; called by muse, mutect2, varscan2
- IRS1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59335484; called by muse, mutect2, varscan2
- IRX2 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57410693; called by muse, mutect2, varscan2
- ITGAE | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1381750714, COSV53992883; called by muse, mutect2
- ITGAM | c.3323C>T p.P1108L (on ENST00000648685 / NM_001145808.2; = p.P1107L on NM_000632.4) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV54936279; called by muse, mutect2, varscan2
- ITIH4 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as rs377477789, COSV56573320; called by muse, mutect2, varscan2
- ITPKB | c.2451G>T p.K817N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55260313; called by muse, mutect2
- ITSN1 | c.3155C>T p.S1052F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66082592; called by muse, mutect2, varscan2
- JAG2 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as COSV59308213; called by muse, mutect2
- JAKMIP1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV51527978; called by muse, mutect2, varscan2
- JAKMIP2 | c.1075T>A p.S359T | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV54602136; called by muse, mutect2, varscan2
- JPT1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1396407786, COSV59173228; called by muse, mutect2, varscan2
- KALRN | c.6046C>T p.H2016Y (on ENST00000360013 / NM_001024660.4; = p.H319Y on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV52254697, COSV52260103; called by muse, mutect2, varscan2
- KANSL3 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as rs546859652, COSV62616581; called by muse, mutect2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 18/116 reads (16%) | catalogued as rs774820321; called by mutect2, varscan2
- KCNA3 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV63901343; called by muse, mutect2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNC4 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs144762287; called by muse, mutect2
- KCNH8 | c.2588C>G p.T863S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV60461501; called by muse, mutect2, varscan2
- KCNJ12 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs377399304; called by muse, mutect2, varscan2
- KCNJ3 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54534981; called by muse, mutect2, varscan2
- KCNJ4 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 94/446 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57856797; called by muse, mutect2, varscan2
- KCNJ6 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55712686; called by muse, mutect2, varscan2
- KCNQ5 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs920140431, COSV59649400, COSV59676282; called by muse, mutect2, varscan2
- KDF1 | c.429del p.S144Afs*104 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as COSV57671558; called by mutect2, pindel, varscan2
- KIAA1522 | c.2737T>C p.F913L (on ENST00000373480 / NM_001198972.2; = p.F972L on NM_020888.3) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53863842; called by muse, mutect2, varscan2
- KIAA1549 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV54311686; called by muse, mutect2, varscan2
- KIAA1586 | c.619del p.I207Lfs*17 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs746314511; called by mutect2, varscan2
- KIF13B | c.3803G>A p.R1268H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374014840; called by muse, mutect2, varscan2
- KIF1A | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV57486974; called by muse, mutect2
- KIF1B | c.2707C>T p.R903C (on ENST00000377086 / NM_001365952.1; = p.R857C on NM_015074.3) | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.336); catalogued as rs868254486, COSV55803421; called by muse, mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF26B | c.3515C>T p.T1172M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780936718, COSV63640025; called by muse, mutect2, varscan2
- KIFBP | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62555580; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 29/119 reads (24%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLF15 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56179836; called by muse, mutect2, varscan2
- KLF3 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54710421; called by muse, mutect2
- KLHL22 | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56731821; called by muse, mutect2
- KLHL25 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV61994833, COSV61996064; called by muse, mutect2
- KMT2B | c.3602del p.P1201Rfs*154 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as COSV55870773; called by mutect2, pindel, varscan2
- KMT2D | c.15476G>A p.R5159Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1205083140, COSV56430096; called by muse, mutect2, varscan2
- KMT2D | c.4360A>G p.T1454A | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56430153; called by muse, mutect2, varscan2
- KMT2D | c.588_589insA p.C197Mfs*23 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as COSV99985279; called by mutect2, pindel, varscan2
- KRT16 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1345833100, COSV56967681; called by muse, mutect2, varscan2
- KRT17 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs200256057, COSV60860104, COSV60860584; called by muse, mutect2, varscan2
- KRT6A | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); catalogued as COSV58104728; called by muse, mutect2, varscan2
- KRT73 | c.1612del p.T538Pfs*2 | Frame Shift Del (DEL) | VAF 54/232 reads (23%) | catalogued as rs747582553; called by mutect2, varscan2
- KRT73 | c.158del p.G53Vfs*65 | Frame Shift Del (DEL) | VAF 29/173 reads (17%) | catalogued as rs745616492, COSV99988806; called by mutect2, pindel, varscan2
- LAMB1 | c.3460G>A p.V1154I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs146247883; called by muse, mutect2, varscan2
- LAMB2 | c.4037G>A p.R1346H | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs149144377; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 27/103 reads (26%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCTL | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs202220021, COSV58421875; called by muse, mutect2, varscan2
- LEPR | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs776269726, COSV62747065; called by muse, mutect2, varscan2
- LHX9 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61328224; called by muse, mutect2, varscan2
- LIMK2 | c.571A>G p.S191G | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV59182131; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs755621588, COSV53276604; called by muse, mutect2
- LRIT1 | c.161del p.P54Rfs*114 | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | catalogued as rs1370241998; called by mutect2, pindel, varscan2
- LRP1B | c.10433C>A p.P3478H | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67183177; called by muse, mutect2, varscan2
- LRP1B | c.4974G>A p.W1658* | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | catalogued as COSV101259979; called by muse, mutect2
- LRP2 | c.13643A>T p.D4548V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55549765; called by muse, mutect2, varscan2
- LRP2 | c.3256T>C p.C1086R | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55549775; called by muse, mutect2, varscan2
- LRRIQ4 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV61618992; called by muse, mutect2, varscan2
- LRRK1 | c.4975C>T p.R1659W | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1015630432, COSV52608388; called by muse, mutect2, varscan2
- LSM14B | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.106); catalogued as COSV53379917; called by muse, mutect2, varscan2
- LY6D | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV56660974; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100235766; called by muse, mutect2, varscan2
- LYST | c.7302A>G p.I2434M | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV67706127; called by muse, mutect2, varscan2
- M1AP | c.74T>A p.L25H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51844008; called by muse, mutect2, varscan2
- MACF1 | c.5277A>T p.E1759D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as rs763425183, COSV57117660; called by muse, mutect2, varscan2
- MADD | c.2899C>T p.R967C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774124659, COSV60623023; called by muse, mutect2, varscan2
- MAF | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251371757, COSV58153699; called by muse, mutect2
- MAG | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV62700123; called by muse, mutect2
- MAGEL2 | c.3044A>C p.Q1015P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100046167; called by mutect2, varscan2
- MAN2C1 | c.2796G>T p.L932F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.642); catalogued as COSV51227879; called by muse, mutect2, varscan2
- MAP2K2 | c.875A>G p.H292R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.079); catalogued as rs1261950218, COSV53564362; called by muse, mutect2
- MAP3K13 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53987458; called by muse, mutect2, varscan2
- MAP3K7 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1040962323, COSV65224159; called by muse, mutect2, varscan2
- MARK1 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs373048949; called by muse, mutect2, varscan2
- MAST1 | c.4289G>A p.G1430D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52245016, COSV52248025; called by mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as rs746267361; called by mutect2, varscan2
- MCAT | c.1023del p.F342Sfs*7 | Frame Shift Del (DEL) | VAF 57/353 reads (16%) | catalogued as COSV51792007; called by mutect2, pindel, varscan2
- MCRS1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57790384; called by muse, mutect2, varscan2
- MDC1 | c.3983C>T p.T1328I | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1335746213, COSV64524199; called by muse, mutect2, varscan2
- MEGF9 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV64235210; called by muse, mutect2, varscan2
- MEX3A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs771196067, COSV64142001; called by muse, mutect2, varscan2
- MICU2 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV66673722, COSV66675293; called by mutect2, varscan2
- MIDEAS | c.1134T>G p.H378Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV54094203; called by muse, mutect2, varscan2
- MIPEP | c.2035A>G p.M679V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs1454124899, COSV66300328; called by muse, mutect2, varscan2
- MKRN3 | c.1309T>C p.S437P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV58809534; called by muse, mutect2, varscan2
- MMP9 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1247744387, COSV63433961; called by muse, mutect2, varscan2
- MMP9 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.414); catalogued as COSV63433963; called by muse, mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs757379917; called by mutect2, varscan2
- MORC2 | c.1459C>T p.R487C (on ENST00000397641 / NM_001303256.3; = p.R425C on NM_014941.3) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs780264849, COSV53197987; called by muse, mutect2, varscan2
- MORN3 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs190870395, COSV62507219; called by muse, mutect2, varscan2
- MPV17L2 | c.493dup p.Q165Pfs*175 | Frame Shift Ins (INS) | VAF 22/114 reads (19%) | catalogued as rs746591385; called by mutect2, varscan2
- MRC2 | c.3976C>T p.R1326W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as rs182449556, COSV57638885; called by muse, mutect2, varscan2
- MSLN | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs150147307; called by muse, mutect2, varscan2
- MTCL1 | c.5363G>A p.R1788Q (on ENST00000306329 / NM_001378206.1; = p.R1469Q on NM_015210.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as rs770565324, COSV60403340; called by muse, mutect2, varscan2
- MTSS1 | c.2228_2230del p.K743del | In Frame Del (DEL) | VAF 36/188 reads (19%) | catalogued as rs1164228041; called by pindel, varscan2
- MTSS1 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs912241708, COSV52674403; called by muse, mutect2, varscan2
- MTUS2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373199820; called by muse, mutect2, varscan2
- MUC16 | c.40753A>G p.T13585A | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV66691278; called by muse, mutect2, varscan2
- MUC16 | c.32528del p.F10843Sfs*11 | Frame Shift Del (DEL) | VAF 19/127 reads (15%) | catalogued as COSV67467225; called by mutect2, pindel, varscan2
- MUC17 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV60286029; called by muse, mutect2, varscan2
- MUC2 | c.2902G>A p.V968I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs572797801; called by muse, mutect2
- MYBL1 | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV72918913; called by muse, mutect2, varscan2
- MYF6 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs999082310, COSV57351330; called by muse, mutect2
- MYH14 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776632941, COSV51815079; called by muse, mutect2, varscan2
- MYO15A | c.7613C>T p.A2538V | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV52755301; called by muse, mutect2, varscan2
- N4BP3 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751253637, COSV51062277; called by muse, mutect2, varscan2
- NAB1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.183); catalogued as rs555592626, COSV61608587; called by muse, mutect2, varscan2
- NACC1 | c.1432A>G p.K478E | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52834416; called by muse, mutect2, varscan2
- NALCN | c.1558A>G p.M520V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV51930257; called by muse, mutect2
- NALCN | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315315157, COSV51930283; called by muse, mutect2, varscan2
- NAT10 | c.2918A>G p.N973S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV57663243; called by muse, mutect2, varscan2
- NAV1 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV55216549; called by muse, mutect2
- NCAPG2 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV51986884; called by muse, mutect2, varscan2
- NCOA6 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1330771895, COSV100750465, COSV62862902; called by muse, mutect2, varscan2
- NDUFA10 | c.604dup p.H202Pfs*25 | Frame Shift Ins (INS) | VAF 24/114 reads (21%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NDUFS6 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV56876449; called by muse, mutect2
- NEBL | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs142138590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEFM | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV55330703; called by muse, mutect2
- NELFCD | c.919G>A p.A307T (on ENST00000602795; = p.A289T on NM_198976.4) | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.478); catalogued as COSV53882999; called by muse, mutect2, varscan2
- NEUROG3 | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV54342669; called by muse, mutect2, varscan2
- NFAT5 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63026708; called by muse, mutect2, varscan2
- NFATC2 | c.1944G>T p.K648N | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV65354998; called by muse, mutect2
- NFATC2 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167540083, COSV65355005; called by muse, mutect2, varscan2
- NFE2L1 | c.485dup p.V163Sfs*14 | Frame Shift Ins (INS) | VAF 17/125 reads (14%) | catalogued as rs773403681; called by mutect2, varscan2
- NIBAN3 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); catalogued as COSV53108502; called by muse, mutect2, varscan2
- NIPBL | c.5573T>C p.L1858S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56949210; called by muse, varscan2
- NKIRAS1 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV66248224; called by muse, mutect2, varscan2
- NLGN4Y | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1375883113, COSV100197084; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NOL4L | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs374479145, COSV62889078; called by muse, mutect2, varscan2
- NOTCH2 | c.4355G>T p.G1452V | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56691317, COSV99866478; called by muse, mutect2
- NOTCH3 | c.4898C>T p.P1633L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.307); catalogued as rs375474414, COSV54644910; called by muse, mutect2, varscan2
- NPAS3 | c.1583G>A p.S528N (on ENST00000356141 / NM_001164749.2; = p.S496N on NM_022123.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as COSV60830829; called by muse, mutect2, varscan2
- NPM2 | c.532-2A>G p.X178_splice | Splice Site (SNP) | VAF 8/150 reads (5%) | catalogued as COSV57075535; called by muse, mutect2
- NPTX2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs565519639, COSV55716887; called by muse, mutect2, varscan2
- NSD3 | c.4003A>G p.M1335V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV57668620; called by muse, mutect2, varscan2
- NSD3 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1486424960, COSV57618140; called by muse, mutect2
- NT5C1A | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.942); catalogued as rs1289830312, COSV52493247; called by muse, mutect2, varscan2
- NUMA1 | c.3499_3500del p.L1167Afs*39 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as rs988705691; called by pindel, varscan2
- OBSL1 | c.5510del p.G1837Afs*57 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs755333275, COSV54710993; called by mutect2, pindel, varscan2
- OBSL1 | c.4334G>A p.R1445Q | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); catalogued as rs372036582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OPRL1 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs777074407, COSV61091411; called by muse, mutect2, varscan2
- OR10K2 | c.753C>A p.H251Q | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59220997; called by muse, mutect2, varscan2
- OR1Q1 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52917731; called by muse, mutect2, varscan2
- OR2T12 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100527946; called by muse, mutect2, varscan2
- OR4C16 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs768595930, COSV58940480; called by muse, mutect2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52B6 | c.365T>G p.F122C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61447711; called by muse, mutect2, varscan2
- OR52K2 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1432902967, COSV57834961; called by muse, mutect2, varscan2
- OR5AR1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV57253554; called by muse, mutect2, varscan2
- OR5AR1 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs754489483, COSV57253574; called by muse, mutect2, varscan2
- OR5P3 | c.50T>C p.L17S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60429185; called by muse, mutect2
- OR6Y1 | c.873C>A p.N291K | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777331640, COSV56929108; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as CD124838, COSV100258088; called by mutect2, pindel, varscan2
- OVOL2 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99602580; called by muse, mutect2, varscan2
- OXCT2 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.918); catalogued as rs1262186887, COSV59593559, COSV59594750; called by muse, mutect2, varscan2
- P2RX3 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758914483, COSV54442212; called by muse, mutect2, varscan2
- PAM | c.791A>C p.Q264P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57212184, COSV57215405; called by muse, mutect2, varscan2
- PAQR9 | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV61417955, COSV61418458; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs772816756; called by mutect2, pindel
- PCDH11Y | c.1583G>T p.G528V (on ENST00000400457 / NM_032973.2; = p.G517V on NM_032971.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53079031; called by muse, mutect2, varscan2
- PCDH15 | c.5793A>C p.E1931D | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV57294383; called by muse, mutect2, varscan2
- PCDH17 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); catalogued as COSV64973438, COSV64978031; called by muse, mutect2, varscan2
- PCDH8 | c.1999C>A p.R667S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV58812112; called by muse, mutect2, varscan2
- PCDHA13 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56494033; called by muse, mutect2, varscan2
- PCDHA2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.361); catalogued as COSV65365111; called by muse, mutect2, varscan2
- PCDHA3 | c.596del p.N199Ifs*2 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs782411180, COSV65371489; called by mutect2, varscan2
- PCDHA3 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV63540073; called by muse, mutect2
- PCDHA6 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.125); catalogued as COSV67047023; called by muse, mutect2, varscan2
- PCDHA8 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.085); catalogued as COSV65325508, COSV65331589; called by muse, mutect2, varscan2
- PCDHB6 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV50694084, COSV50742999; called by muse, mutect2, varscan2
- PCDHGA1 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.627); catalogued as rs768240411, COSV65296000; called by muse, varscan2
- PCDHGA7 | c.1295T>C p.L432S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53931015; called by muse, mutect2
- PCDHGB3 | c.1809G>A p.W603* | Nonsense Mutation (SNP) | VAF 20/135 reads (15%) | catalogued as COSV53930997; called by muse, mutect2, varscan2
- PCDHGB4 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs1254438724, COSV53931032; called by muse, mutect2, varscan2
- PCDHGC4 | c.1836G>T p.E612D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV52749323; called by muse, mutect2
- PCYT1B | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV63264662; called by muse, mutect2, varscan2
- PDCD11 | c.4531G>A p.A1511T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV63933677; called by muse, mutect2, varscan2
- PDCD4 | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.074); catalogued as COSV54522488; called by muse, mutect2, varscan2
- PDE1C | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58510997; called by muse, mutect2
- PDE3B | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV56382571; called by muse, mutect2
- PDE3B | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56382581; called by muse, mutect2
- PDE4DIP | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as rs1399881821, COSV57691112, COSV57722368; called by muse, mutect2, varscan2
- PDIA4 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53724371; called by muse, mutect2, varscan2
- PDZRN4 | c.1551A>C p.E517D (on ENST00000402685 / NM_001164595.2; = p.E259D on NM_013377.4) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.549); catalogued as COSV54198598; called by muse, mutect2
- PFKFB1 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | PolyPhen probably damaging (1); catalogued as rs140853589, COSV66628133; called by mutect2, varscan2
- PGAP6 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51738850; called by muse, mutect2, varscan2
- PGD | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54621118; called by muse, mutect2, varscan2
- PGLYRP2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535549580, COSV52993092; called by muse, mutect2, varscan2
- PHKB | c.1461C>T p.G487= | Splice Region (SNP) | VAF 11/67 reads (16%) | catalogued as COSV54519407; called by muse, mutect2, varscan2
- PHKB | c.1929del p.G644Efs*2 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | catalogued as rs35494330; called by mutect2, pindel, varscan2
- PHKG2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs746541930, COSV100079782; called by muse, mutect2, varscan2
- PIGC | c.247del p.H83Ifs*4 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | catalogued as rs1176830810; called by mutect2, pindel, varscan2
- PIGT | c.1043del p.P348Qfs*11 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs749895437; called by mutect2, pindel, varscan2
- PIK3CG | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs554272230, COSV63247299; called by muse, mutect2, varscan2
- PIK3R2 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1165324884, COSV55847655; called by muse, mutect2, varscan2
- PKP4 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as rs764636523, COSV61578466; called by muse, mutect2, varscan2
- PLB1 | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs180811630; called by muse, mutect2, varscan2
- PLCXD1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs778506926, COSV58204803; called by muse, mutect2, varscan2
- PLEKHA5 | c.3314C>T p.P1105L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs774894158, COSV54695622; called by muse, mutect2, varscan2
- PLEKHG1 | c.3079G>T p.G1027* | Nonsense Mutation (SNP) | VAF 29/129 reads (22%) | catalogued as COSV62046739; called by muse, mutect2, varscan2
- PLPBP | c.696+2T>C p.X232_splice | Splice Site (SNP) | VAF 25/133 reads (19%) | catalogued as COSV60239569; called by muse, mutect2, varscan2
- PLXNA4 | c.4141C>T p.R1381C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1174677476, COSV58104016; called by muse, mutect2, varscan2
- PLXNC1 | c.3793C>T p.R1265* | Nonsense Mutation (SNP) | VAF 19/115 reads (17%) | catalogued as rs747289625, COSV51573732; called by muse, mutect2, varscan2
- PNPLA7 | c.2876G>A p.G959D | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753945090, COSV52997633; called by muse, mutect2, varscan2
- POLDIP3 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs113566870, COSV52808891; called by muse, mutect2, varscan2
- POLE2 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773570956, COSV53559408; called by muse, mutect2, varscan2
- POLH | c.538A>T p.I180F | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV64779308; called by muse, mutect2, varscan2
- POLRMT | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1339218084, COSV73933205; called by muse, mutect2, varscan2
- POP1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs144135573; called by muse, mutect2, varscan2
- POP4 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs759908705, COSV55676291; called by muse, mutect2, varscan2
- POU3F3 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV63721572; called by muse, mutect2, varscan2
- PPM1M | c.299G>A p.R100Q (on ENST00000296487; = p.R261Q on NM_144641.4) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763280867, COSV56599113; called by muse, mutect2
- PPP1CC | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.149); catalogued as COSV58583209; called by muse, mutect2
- PPP3CC | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196783532, COSV51500571; called by muse, mutect2
- PPP4C | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54221626; called by muse, mutect2, varscan2
- PRAME | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV67161401; called by muse, mutect2, varscan2
- PRF1 | c.1288del p.D430Tfs*10 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as CM077758; called by mutect2, pindel, varscan2
- PRKAA1 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.957); catalogued as COSV57183774; called by muse, mutect2, varscan2
- PRKACG | c.22_24del p.K8del | In Frame Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs757053828; called by pindel, varscan2
- PRKCD | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV57847930; called by muse, mutect2, varscan2
- PRKD1 | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100121985, COSV59565714; called by muse, mutect2, varscan2
- PRKRA | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV57868487; called by muse, mutect2, varscan2
- PROM2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs1161628972, COSV58297664; called by muse, mutect2
- PRPF40B | c.1195G>A p.A399T (on ENST00000380281; = p.A393T on NM_012272.3) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV56059039; called by muse, mutect2
- PRPF8 | c.2533C>T p.R845W | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59262590; called by muse, mutect2, varscan2
- PRR5 | c.460A>G p.N154D (on ENST00000336985 / NM_181333.4; = p.N145D on NM_015366.4) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.989); catalogued as COSV50059613; called by muse, mutect2
- PRRC2C | c.1978G>A p.A660T (on ENST00000367742; = p.A658T on NM_015172.4) | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV58904085; called by muse, mutect2
- PRSS35 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1408200027, COSV63800432; called by muse, mutect2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PRUNE2 | c.1760T>C p.L587P | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65040606; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 32/131 reads (24%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTGR1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs376212074; called by muse, mutect2, varscan2
- PTPRCAP | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100396729; called by muse, mutect2, varscan2
- PTPRE | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54549676; called by muse, mutect2, varscan2
- PTPRG | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1559731824, COSV55637474; called by muse, mutect2, varscan2
- PTPRJ | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755218393, COSV69250194, COSV69253020; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs772722517, COSV99560265; called by mutect2, pindel, varscan2
- PUS7L | c.657del p.F219Lfs*47 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as COSV61261475; called by mutect2, pindel, varscan2
- PYDC1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV57250938; called by muse, mutect2, varscan2
- PYGB | c.1401G>T p.S467= | Splice Region (SNP) | VAF 22/112 reads (20%) | catalogued as COSV53817719, COSV53821557; called by muse, mutect2, varscan2
- PYGM | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs757387408, COSV51216012; called by muse, mutect2, varscan2
- PYGO1 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57347374; called by muse, mutect2, varscan2
- PYGO2 | c.448dup p.Q150Pfs*27 | Frame Shift Ins (INS) | VAF 14/94 reads (15%) | catalogued as rs748504064; called by mutect2, varscan2
- PYROXD1 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as COSV53709211; called by muse, mutect2, varscan2
- RAB35 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57567453; called by muse, mutect2, varscan2
- RAB40AL | c.479A>T p.N160I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54434084; called by muse, mutect2, varscan2
- RABL2B | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.933); catalogued as COSV61483408; called by mutect2, varscan2
- RAD21 | c.1690C>T p.L564F | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as COSV52058219; called by muse, mutect2, varscan2
- RAD50 | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs753002904, COSV54748210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAG2 | c.1524del p.G509Vfs*6 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | catalogued as COSV100271291, COSV57558940; called by mutect2, pindel, varscan2
- RALGAPA1 | c.5482A>G p.N1828D | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338209548, COSV51880955; called by muse, mutect2, varscan2
- RALGAPA2 | c.5452G>A p.A1818T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246043511, COSV52486734, COSV52494684; called by muse, mutect2
- RANBP2 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 107/481 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs770003253, COSV51699667; called by muse, mutect2, varscan2
- RAP1B | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51668117; called by muse, mutect2, varscan2
- RAPGEF4 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV51384833; called by muse, mutect2, varscan2
- RAPGEF4 | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.153); catalogued as rs1267487098, COSV51384881; called by muse, mutect2, varscan2
- RASAL2 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as rs1370663764, COSV62712679; called by muse, mutect2, varscan2
- RASAL2 | c.722del p.K241Rfs*7 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs771909008; called by mutect2, varscan2
- RBAK-RBAKDN | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs747449091, COSV101208273; called by muse, mutect2, varscan2
- RBBP4 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65132422; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBL1 | c.431del p.L144* | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as COSV60328025; called by mutect2, pindel
- RBM47 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV55933789, COSV55936265; called by muse, mutect2, varscan2
- RC3H2 | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.189); catalogued as COSV61799561; called by muse, mutect2, varscan2
- RCC1L | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57320144; called by muse, mutect2
- RELN | c.8288G>A p.C2763Y | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV58997007; called by muse, mutect2, varscan2
- REPS1 | c.1376C>A p.T459N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99238990; called by muse, mutect2
- REV3L | c.8156C>T p.A2719V | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs376298082; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | catalogued as rs751982308; called by mutect2, varscan2
- RGS5 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); catalogued as rs754717880, COSV58352086; called by muse, mutect2, varscan2
- RIMS1 | c.901del p.V301Wfs*61 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as COSV99326135; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 34/193 reads (18%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs752898741; called by mutect2, varscan2
- ROM1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.229); catalogued as COSV53882055; called by muse, mutect2, varscan2
- ROR2 | c.1010G>A p.C337Y | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65218353; called by muse, mutect2, varscan2
- RP1 | c.4175A>G p.N1392S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as rs780518944, COSV55114888; called by muse, mutect2, varscan2
- RPTOR | c.2000T>C p.L667P | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60807241; called by muse, mutect2, varscan2
- RPUSD2 | c.1130A>G p.Q377R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242435256, COSV59765247; called by muse, mutect2, varscan2
- RSBN1L | c.94T>G p.S32A | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV58507757; called by muse, mutect2, varscan2
- RSPH6A | c.1985C>A p.P662Q | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54288715; called by muse, varscan2
- RTF2 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as rs1220633709, COSV50128320; called by muse, mutect2, varscan2
- SAE1 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV54294399; called by muse, varscan2
- SAE1 | c.1001T>C p.M334T | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV54294409; called by muse, mutect2
- SALL3 | c.2907G>T p.R969S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV73305964, COSV73306456; called by muse, mutect2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | catalogued as COSV59083791; called by mutect2, varscan2
- SBF1 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs1365471017, COSV62367180; called by muse, mutect2, varscan2
- SBNO2 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.478); catalogued as COSV62320059; called by muse, mutect2, varscan2
- SCN10A | c.4727G>A p.R1576H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs777606824, COSV71860179; called by muse, mutect2, varscan2
- SECISBP2L | c.439T>C p.C147R | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV55933917; called by muse, mutect2, varscan2
- SEMA3C | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.129); catalogued as COSV54844933; called by muse, mutect2
- SEMA5B | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs772803361, COSV52095758; called by muse, mutect2, varscan2
- SERPINB12 | c.449del p.N150Tfs*39 | Frame Shift Del (DEL) | VAF 16/113 reads (14%) | catalogued as rs760486497; called by mutect2, pindel, varscan2
- SETD5 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 20/133 reads (15%) | catalogued as COSV56709783; called by muse, mutect2, varscan2
- SF3B2 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs200930603, COSV100488522, COSV59427692; called by muse, mutect2, varscan2
- SH2D3C | c.1571G>T p.R524M (on ENST00000314830 / NM_170600.3; = p.R367M on NM_005489.4) | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV59121622; called by muse, mutect2
- SHANK1 | c.5401C>T p.R1801C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs745777736, COSV53247867, COSV99035839; called by muse, mutect2, varscan2
- SHANK2 | c.5278C>T p.R1760C | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV53594633; called by muse, mutect2, varscan2
- SHANK3 | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs770978141, COSV53185707; called by muse, mutect2
- SIGLEC12 | c.461A>C p.E154A (on ENST00000291707 / NM_053003.4; = p.E36A on NM_033329.2) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.593); catalogued as COSV52460879; called by muse, mutect2, varscan2
- SIGLEC9 | c.1088_1090del p.F363del | In Frame Del (DEL) | VAF 35/185 reads (19%) | catalogued as rs1271961723; called by mutect2, pindel, varscan2
- SIX4 | c.137del p.P46Rfs*20 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs776137605; called by mutect2, varscan2
- SIX5 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52177314; called by muse, mutect2, varscan2
- SKIV2L | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1017591846, COSV61713307; called by muse, mutect2, varscan2
- SLC14A2 | c.2029A>G p.M677V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99676049; called by muse, mutect2, varscan2
- SLC16A14 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1205196087, COSV54617922; called by muse, mutect2
- SLC22A16 | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57929104; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs749849908; called by mutect2, pindel, varscan2
- SLC24A2 | c.99dup p.L34Tfs*17 | Frame Shift Ins (INS) | VAF 33/189 reads (17%) | catalogued as rs1239413820; called by mutect2, pindel, varscan2
- SLC25A16 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs760386255, COSV56264741; called by muse, mutect2, varscan2
- SLC29A3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.038); catalogued as rs564350775, COSV64384882; called by muse, varscan2
- SLC39A5 | c.1130A>G p.H377R | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV57191432; called by muse, mutect2, varscan2
- SLC3A1 | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM050090, COSV99577532; called by mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC45A2 | c.1244T>G p.I415S | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV56871202; called by muse, mutect2, varscan2
- SLC46A1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.195); catalogued as rs370955621; called by muse, mutect2
- SLC4A5 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772367349, COSV61026835; called by muse, mutect2, varscan2
- SLC9A2 | c.2243del p.P748Qfs*34 | Frame Shift Del (DEL) | VAF 27/200 reads (14%) | catalogued as rs748701652; called by mutect2, pindel, varscan2
- SLC9A3 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1032038566, COSV53800508; called by muse, mutect2, varscan2
- SLC9A5 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as rs759158210, COSV55361554; called by muse, mutect2, varscan2
- SLC9A8 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs755689652, COSV64287723, COSV64288092; called by muse, mutect2, varscan2
- SLCO1B1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs555367334, COSV57009875, COSV57011549; called by muse, mutect2, varscan2
- SLFN5 | c.2093del p.P698Lfs*21 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as rs745817019; called by mutect2, pindel, varscan2
- SMCP | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as rs1283040168, COSV64217643; called by muse, mutect2, varscan2
- SMTNL2 | c.1280G>A p.R427H (on ENST00000389313 / NM_001114974.2; = p.R283H on NM_198501.3) | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141427435; called by muse, mutect2, varscan2
- SNAI2 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs915887115, COSV50078908, COSV99195008; called by muse, mutect2, varscan2
- SNAPC2 | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV54491022; called by muse, mutect2
- SND1 | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs752279583, COSV100690799, COSV61239329; called by muse, mutect2, varscan2
- SNRNP200 | c.4885C>T p.R1629* | Nonsense Mutation (SNP) | VAF 18/137 reads (13%) | catalogued as COSV60487713; called by muse, mutect2, varscan2
- SNTG1 | c.681-2A>G p.X227_splice | Splice Site (SNP) | VAF 19/92 reads (21%) | catalogued as COSV52438130; called by muse, mutect2, varscan2
- SNX18 | c.635_636insA p.Q213Afs*139 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | catalogued as COSV57988284; called by mutect2, pindel
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX31 | c.256+2T>C p.X86_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV61262758; called by muse, mutect2, varscan2
- SOGA3 | c.2254G>A p.D752N | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64106236; called by muse, mutect2
- SOHLH1 | c.599C>A p.T200K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as COSV53681321; called by muse, mutect2, varscan2
- SOHLH2 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV58521593; called by muse, mutect2
- SORL1 | c.1639G>A p.G547R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342620909, COSV52752827; called by muse, mutect2
- SORL1 | c.5161G>A p.V1721I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.086); catalogued as rs766211371, COSV52752839; called by muse, mutect2, varscan2
- SPDYC | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as COSV65865097; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPECC1L | c.3292C>T p.R1098* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV58657831; called by muse, mutect2, varscan2
- SPEG | c.8681T>G p.V2894G | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV56667148; called by muse, mutect2, varscan2
- SPHKAP | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60875632, COSV60879813; called by muse, mutect2, varscan2
- SPON1 | c.689A>G p.H230R | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV59959887; called by muse, mutect2
- SPTA1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); catalogued as rs1325208281, COSV100935485, COSV63751842; called by muse, mutect2, varscan2
- SPTAN1 | c.2929G>A p.D977N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV63986566, COSV63991148; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 38/140 reads (27%) | catalogued as rs748467821; called by mutect2, varscan2
- SRD5A2 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV51871225; called by muse, mutect2, varscan2
- SREBF1 | c.1761G>C p.K587N | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV55416076, COSV55418260; called by muse, mutect2
- SREBF2 | c.2293del p.L765Wfs*13 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | catalogued as COSV63331442; called by mutect2, pindel, varscan2
- SRPRA | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs201079010; called by muse, mutect2, varscan2
- SRRT | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.185); catalogued as COSV61451923; called by muse, varscan2
- SSH1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs199897989, COSV58455330; called by muse, mutect2, varscan2
- SSTR4 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs1339869906, COSV54797662; called by muse, mutect2, varscan2
- ST6GAL2 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | PolyPhen benign (0.235); catalogued as rs763586738, COSV64526667; called by muse, mutect2
- ST8SIA6 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as COSV66467550; called by muse, mutect2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs747316268, COSV52690552; called by mutect2, pindel, varscan2
- SULT1C3 | c.41del p.K14Sfs*10 | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | catalogued as rs770034585; called by mutect2, pindel, varscan2
- SV2C | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59218545; called by muse, mutect2, varscan2
- SVEP1 | c.5814G>T p.Q1938H | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV52838258; called by muse, mutect2, varscan2
- SVIL | c.2379G>T p.K793N (on ENST00000355867 / NM_021738.3; = p.K367N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV63442504; called by muse, mutect2, varscan2
- SWT1 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as rs1470673561, COSV100833480; called by muse, mutect2
- SYCP2 | c.2533A>G p.K845E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV62767734; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNE2 | c.8968G>A p.A2990T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs748085293, COSV59947376; called by muse, mutect2, varscan2
- SYNGAP1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as rs1034171771, COSV53380455; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNJ2 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs951729369, COSV62896069; called by muse, mutect2
- SYT1 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54043016; called by muse, mutect2, varscan2
- SYTL1 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs1335337128, COSV58871326; called by muse, mutect2, varscan2
- SYTL2 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs371521597, COSV60358122; called by muse, mutect2, varscan2
- SZT2 | c.8027G>A p.R2676Q (on ENST00000634258 / NM_001365999.1; = p.R2619Q on NM_015284.4) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs758138686, COSV65169144; called by muse, mutect2, varscan2
- TAAR2 | c.825G>A p.W275* (on ENST00000367931 / NM_001033080.1; = p.W230* on NM_014626.3) | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV51578947; called by muse, varscan2
- TAAR2 | c.769G>A p.D257N (on ENST00000367931 / NM_001033080.1; = p.D212N on NM_014626.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV51578953; called by muse, varscan2
- TAB1 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as rs368216070, COSV53370776; called by muse, mutect2, varscan2
- TADA2B | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.31); catalogued as COSV53827121; called by muse, mutect2, varscan2
- TAF1B | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs750356942, COSV55154448; called by muse, mutect2, varscan2
- TAF4 | c.2087T>C p.V696A | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV53336822; called by muse, mutect2, varscan2
- TAOK2 | c.2276C>A p.P759H | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV54235007; called by muse, mutect2, varscan2
- TAOK3 | c.931dup p.I311Nfs*13 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | catalogued as rs1346340006; called by mutect2, varscan2
- TARS2 | c.403A>G p.S135G | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs913776797, COSV64695145; called by muse, mutect2, varscan2
- TAS2R38 | c.80C>A p.A27E | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as COSV71885297; called by muse, mutect2, varscan2
- TAS2R5 | c.832A>G p.R278G | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV56094749; called by muse, mutect2
- TBK1 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59154779; called by muse, mutect2
- TBX18 | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63736611; called by muse, mutect2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF7L2 | c.1536del p.S513Pfs*5 (on ENST00000355995 / NM_001367943.1; = p.S490Pfs*5 on NM_030756.5) | Frame Shift Del (DEL) | VAF 22/163 reads (13%) | catalogued as rs748822481, COSV53340400; called by mutect2, pindel, varscan2
- TDRD6 | c.2710C>T p.Q904* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as COSV60175104; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 54/297 reads (18%) | catalogued as rs763321097; called by mutect2, varscan2
- TECTA | c.5410G>T p.V1804L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.967); catalogued as COSV50701188; called by muse, mutect2, varscan2
- TEFM | c.646-2del p.X216_splice | Splice Site (DEL) | VAF 8/60 reads (13%) | catalogued as rs752803488; called by mutect2, pindel
- TERB2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as rs1181743604, COSV61650675; called by muse, mutect2, varscan2
- TET3 | c.1135del p.Q379Rfs*162 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as COSV59880837; called by mutect2, pindel, varscan2
- TFIP11 | c.1229A>C p.K410T | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.321); catalogued as COSV53226000; called by muse, mutect2, varscan2
- TGFB3 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757774610, COSV53169386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THBS1 | c.3125A>G p.Q1042R | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52951417; called by muse, mutect2
- THBS4 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs371339729; called by muse, mutect2, varscan2
- THNSL2 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs762928781, COSV59082697; called by muse, mutect2
- THY1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs766870633, COSV52454179; called by muse, mutect2, varscan2
- TIGD2 | c.1548del p.K516Nfs*24 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs758519530; called by mutect2, pindel, varscan2
- TIGD3 | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV52888945; called by muse, mutect2
- TJAP1 | c.1064G>A p.R355H (on ENST00000372445 / NM_001146016.1; = p.R345H on NM_080604.3) | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868241056, COSV52500515; called by muse, mutect2, varscan2
- TJP3 | c.2484del p.Y830Tfs*64 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as rs748320679, COSV99515633; called by mutect2, pindel, varscan2
- TLE2 | c.91_93del p.E31del | In Frame Del (DEL) | VAF 17/130 reads (13%) | catalogued as rs752733064; called by pindel, varscan2
- TLK2 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 10/89 reads (11%) | catalogued as rs779826427; called by pindel, varscan2
- TMC2 | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV100727925; called by muse, mutect2, varscan2
- TMEM109 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs375366268; called by muse, mutect2, varscan2
- TMEM198 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs763015024, COSV54717319; called by muse, mutect2, varscan2
- TMEM252 | c.100T>C p.F34L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV66065536; called by muse, mutect2, varscan2
- TMEM63C | c.1525G>T p.G509* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | catalogued as COSV53602966; called by muse, mutect2
- TMEM68 | c.229A>G p.K77E | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV58170554; called by muse, mutect2, varscan2
553 further variants in this file (232 protein-altering or splice-affecting, 291 silent, 30 other) are not listed here.
